Gene-level copy-number profile of tumor specimen BLGSP-71-32-00694-01A from CGCI case BLGSP-71-32-00694, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 66.9 years (24,421 days).
Specimen BLGSP-71-32-00694-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1bfbd6a6-202a-4ac9-9301-e0312457e099.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-32-00694-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/dc03a242-f438-4e2c-9a2a-61a9aa016b6c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 2,839; copy number 3: 1,935; copy number 4: 51,810; copy number 5: 1,526; copy number 6: 517; copy number 7: 174; copy number 8: 41; copy number 9: 34; copy number 10: 10; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 45 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,691,673–89,143,160, 32 genes, copy number 9–10 (within-gene range 9–11): RPIA, ANKRD36BP2, MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20.
- chr2:89,968,867–90,083,291, 12 genes, copy number 9: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17.
- chr2:90,114,838–90,115,402, 1 gene, copy number 14 (within-gene range 7–14): IGKV3D-15.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
